Somatic mutation profile of tumor specimen BA2752D (aliquot aq-BA2752D) from BEATAML1.0 case 2208, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 68.1 years (24,888 days).
Specimen BA2752D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 057f4ad7-94e3-45a1-a870-41ed7533de54.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2189D (Solid Tissue Normal), aliquot aq-BA2189D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/41e3dd11-65a1-4c39-8731-a71078b8a57d

The open-access MAF lists 13 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 2, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 42/258 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- GUCA2B | c.316G>A p.V106I | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.094); catalogued as rs770549769, COSV65367880; called by muse, mutect2, varscan2
- MUC17 | c.9840C>G p.S3280R | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100072831; called by muse, mutect2, varscan2
- SUDS3 | c.787T>C p.Y263H | Missense Mutation (SNP) | VAF 50/122 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); catalogued as COSV64349133; called by mutect2, varscan2
- TRPV1 | c.1849C>T p.R617W | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.339); catalogued as rs199704222, COSV51516230; called by muse, varscan2
- CHL1 | c.637A>G p.T213A | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- CPT1B | c.1398G>T p.Q466H | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MUC19 | n.5106-1G>A | Splice Site (SNP) | VAF 16/90 reads (18%) | called by muse, mutect2
- NSD1 | c.1718G>A p.C573Y | Missense Mutation (SNP) | VAF 49/131 reads (37%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- TFAP4 | c.386G>T p.R129L | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2
- CELSR2 | c.1671T>C p.N557= | Silent (SNP) | VAF 56/141 reads (40%) | catalogued as rs776778559; called by muse, mutect2, varscan2
- NALCN | c.2067C>T p.C689= | Silent (SNP) | VAF 13/132 reads (10%) | catalogued as rs770448448, COSV51933587, COSV51946325; ClinVar: likely benign; called by muse, mutect2, varscan2
- CKLF | chr16:66566136 C>T | 3'Flank (SNP) | VAF 25/76 reads (33%) | catalogued as rs943845639; called by muse, mutect2, varscan2
